Gene-level copy-number profile of tumor specimen TCGA-23-1121-01A from TCGA case TCGA-23-1121, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.0 years (18,983 days).
Specimen TCGA-23-1121-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5b4a72f9-5cee-49ad-8d8c-1639e20083ce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1121-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e1a3de63-276a-4d1d-933d-b1ea5ae7202b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 7,686; copy number 2: 26,685; copy number 3: 15,927; copy number 4: 5,608; copy number 5: 2,246; copy number 6: 1,127; copy number 7: 142; copy number 8: 246; copy number 9: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1121-01A-01D-0428-01): tumor purity 0.96, ploidy 2.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:3,196,626–5,872,050, 49 genes: AC073316.2, SDK1-AS1, SDK1, AC092427.1, AC011284.1, AC017000.1, CYP3A54P, AC072054.1, FOXK1, AC092428.1, AP5Z1, MIR4656, AC092610.1, RADIL, Y_RNA, PAPOLB, RPL22P16, MMD2, RNF216P1, AC092032.2, RBAK-RBAKDN, AC092032.3, AC092032.1, SPDYE19P, RBAK, RBAKDN, OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1, RNF216, RNF216-IT1, MIR6874, ZNF815P, RN7SL556P.
- chr10:75,552,458–75,743,755, 4 genes: MIR606, AL589863.2, AL589863.1, AL731568.1.
- chr16:59,855,353–64,600,247, 33 genes (within-gene range 0–1): LINC02141, AC009094.1, AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP, AC009169.1, RPS27AP16, AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1, AC040174.1, AC040174.2, UBE2FP2, AC138305.1, RPS15AP34, AC138305.2, AC138305.3, AC018846.1, LINC02165, AC092337.1, AC093536.2, AC012322.1, AC093536.1, AC092131.1.
- chr16:78,981,722–78,981,843, 1 gene: AC027279.3.
- chr18:58,805,268–58,805,374, 1 gene: RNU6-219P.
- chr20:15,892,355–15,985,876, 1 gene (within-gene range 0–1): AL079338.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,805 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:115,029,826–115,622,005, 14 genes, copy number 5: TSHB, TSPAN2, LINC01765, AL049825.1, NGF-AS1, NGF, AL512638.3, AL512638.1, AL512638.2, ELOCP20, CNOT7P2, AL592436.2, RN7SL420P, AL592436.1.
- chr1:165,201,867–189,993,097, 469 genes, copy number 5 (broad region; genes not listed).
- chr3:168,249,522–168,830,599, 1 gene, copy number 6 (within-gene range 4–6): EGFEM1P.
- chr3:168,551,854–175,810,548, 100 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:185,767,847–186,922,753, 42 genes, copy number 5: MIR548AQ, TRA2B, NMRAL2P, ETV5, Metazoa_SRP, ETV5-AS1, DGKG, LINC02020, LINC02052, LINC02051, CRYGS, TBCCD1, DNAJB11, AC068631.1, AC068631.2, AC068631.3, AHSG, Metazoa_SRP, FETUB, HRG, AC109780.1, AC109780.2, KNG1, PSMD10P2, RNU6-1105P, GPS2P2, AC112907.3, EIF4A2, SNORD2, SNORA63B, MIR1248, SNORA81, SNORA63, SNORA4, RFC4, AC112907.1, LINC02043, AC112907.2, ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1.
- chr4:44,533,615–46,124,054, 15 genes, copy number 5 (within-gene range 4–5): AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1, THAP12P9, AC108043.1, RNU6-931P, RN7SKP199, GABRG1.
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr5:58,453,982–63,571,617, 60 genes, copy number 5–7: PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108, RAB3C, AC016642.1, RPL5P15, AC008852.1, PDE4D, AC092343.1, AC008833.1, NDUFB4P2, MIR582, AC034234.1, RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1, DEPDC1B, CAB39P1, AC109133.1, KRT8P31, ELOVL7, ERCC8, GNL3LP1, ERCC8-AS1, NDUFAF2, AC008498.2, AC008498.1, SMIM15, SMIM15-AS1, LINC02057, ZSWIM6, AC122718.2, AC122718.1, RPL3P6, C5orf64, AC026746.1, RNU6-913P, C5orf64-AS1, AC026434.1, AC008877.1, RN7SKP157, KIF2A, AC114982.2, DIMT1, IPO11, RNU6-661P, CKS1BP3, AC114982.1, RPL35AP14, LRRC70, ISCA1P1, AC113420.1, AC025445.1, AC008558.1.
- chr6:167,607–23,031,780, 374 genes, copy number 6–9 (broad region; genes not listed).
- chr6:27,965,175–30,132,966, 155 genes, copy number 6 (broad region; genes not listed).
- chr6:114,477,350–115,002,280, 4 genes, copy number 6 (within-gene range 5–6): AL138830.2, AL138830.1, AL590550.1, RNU6-475P.
- chr6:128,883,138–129,516,566, 1 gene, copy number 6 (within-gene range 3–6): LAMA2.
- chr6:129,157,523–140,205,326, 202 genes, copy number 6 (broad region; genes not listed).
- chr6:145,382,535–145,736,023, 1 gene, copy number 5 (within-gene range 4–5): EPM2A.
- chr6:145,489,630–146,815,462, 18 genes, copy number 5 (within-gene range 3–5): AL031119.1, AL023806.1, AL023806.2, AL023806.5, AL023806.4, AL023806.3, FBXO30, FBXO30-DT, SHPRH, GRM1, FUNDC2P3, RNA5SP222, AL035698.1, RAB32, AL359547.1, ADGB, AL359547.2, RNU6-906P.
- chr6:148,133,809–148,283,408, 3 genes, copy number 5: AL359382.1, AL359382.2, AL513164.1.
- chr6:148,278,672–148,278,778, 1 gene, copy number 5: RNU6-1222P.
- chr7:137,381,037–138,164,637, 13 genes, copy number 5 (within-gene range 4–5): DGKI, AC090498.1, AC009245.1, CREB3L2, CREB3L2-AS1, AKR1D1, AC009263.1, AC024082.1, AC024082.2, RN7SKP223, RCC2P3, MIR4468, AC083867.2.
- chr7:142,111,749–143,313,061, 114 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:144,000,320–144,451,817, 27 genes, copy number 6: OR6B1, OR2A5, OR2A25, OR2A41P, OR2A12, OR2A2, OR2A15P, OR2A14, OR2A13P, OR2A3P, OR2AO1P, CTAGE4, ARHGEF35, ARHGEF35-AS1, OR2A42, OR2A20P, AC074386.1, OR2A7, CTAGE8, ARHGEF34P, OR2A9P, OR2A1-AS1, OR2A1, ARHGEF5, NOBOX, PPIAP83, RNU6ATAC40P.
- chr8:150,584–2,728,577, 54 genes, copy number 5–8 (within-gene range 3–8): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2.
- chr8:40,519,565–51,015,165, 160 genes, copy number 5 (broad region; genes not listed).
- chr8:55,067,585–63,693,249, 130 genes, copy number 5 (broad region; genes not listed).
- chr8:95,947,781–133,963,259, 533 genes, copy number 5–7 (broad region; genes not listed).
- chr10:86,756,601–88,877,544, 63 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr11:55,491,205–57,056,132, 112 genes, copy number 5–8 (broad region; genes not listed).
- chr12:19,089,151–25,250,936, 90 genes, copy number 6 (broad region; genes not listed).
- chr16:9,753,404–11,895,611, 64 genes, copy number 6 (within-gene range 3–10) (broad region; genes not listed).
- chr16:14,275,508–18,598,328, 131 genes, copy number 8 (broad region; genes not listed).
- chr17:76,309,478–80,253,500, 143 genes, copy number 5 (broad region; genes not listed).
- chr17:80,315,651–80,316,633, 1 gene, copy number 5: AC124319.1.

Autosomal genes at a single copy (total copy number 1): 7,522. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
